Surgical pathology report (de-identified scan), TCGA case TCGA-AA-A01K, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-A01K-01A (Primary Tumor).

TCGA #:

Sample ID #:

Diagnosis:

1. Chronically fibrosing cholecystitis, with reactive hyperplasia of a local lymph node.
2. Tumor-free fatty tissue.
3. Resected colon with a centrally ulcerated, moderately differentiated adenocarcinoma of the colorectal type, located 1.5 cm from the aboral resection margin, and with wide infiltration of the pericolic fatty tissue as well as with four local lymph node metastases. Tumor-free colon resection margins. Tumor-free mesocolic resection margin. Also diverticulosis coli.

Stage of tumor: pT3 pN2 (4/35) pMX; G2, L1, V0, local R0.

100-0-3

adenocarcinoma, NOS 8140/3

Site: sigmoid colon (pw CQCF) C18.7

for 3/30/11

Duo-/Synchronous Primary	Noted	

Source: NCI Genomic Data Commons file d81d12bd-b014-473c-aa22-450a3e490916 (TCGA-AA-A01K.0D66971E-D224-4536-A3BE-B138861D8E7D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).